Somatic mutation profile of tumor specimen C3L-02613-02 (aliquot CPT0124610007) from CPTAC case C3L-02613, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 52.2 years (19,066 days).
Specimen C3L-02613-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a48348e9-1d16-4907-90b1-ec5f3e01b641.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02613-31 (Blood Derived Normal), aliquot CPT0124640002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7782097-0117-4c69-9963-ac45720f1307

The open-access MAF lists 170 somatic variants for this specimen: 116 protein-altering or splice-affecting, 35 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 35, Intron 10, Frame Shift Del 7, Nonsense Mutation 6, 5'UTR 3, In Frame Del 3, RNA 3, 5'Flank 2, Splice Site 2, Splice Region 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.798del p.F266Lfs*11 | Frame Shift Del (DEL) | VAF 31/69 reads (45%) | catalogued as rs886040739; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 224/428 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.839G>T p.R280I | Missense Mutation (SNP) | VAF 228/477 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs121912660, CM153865, CM993218, COSV52666248, COSV52677783, COSV52687987; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AKAP12 | c.4234G>A p.V1412I | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs569396619; called by muse, mutect2, varscan2
- ANKRD17 | c.6492G>A p.M2164I | Missense Mutation (SNP) | VAF 103/359 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV58219878; called by muse, mutect2, varscan2
- CDH12 | c.2239G>A p.V747M | Missense Mutation (SNP) | VAF 44/640 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.347); catalogued as rs763180534, COSV66389256; called by muse, mutect2
- CDH23 | c.7714C>A p.Q2572K | Missense Mutation (SNP) | VAF 20/272 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs867364295; called by muse, mutect2
- CELSR3 | c.2110G>A p.A704T | Missense Mutation (SNP) | VAF 90/205 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.769); catalogued as rs767164011; called by muse, mutect2, varscan2
- COBLL1 | c.593T>G p.I198R (on ENST00000392717; = p.I160R on NM_014900.5) | Missense Mutation (SNP) | VAF 57/218 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99528586; called by muse, mutect2, varscan2
- COL6A6 | c.764G>T p.S255I | Missense Mutation (SNP) | VAF 138/380 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.092); catalogued as COSV62031119; called by muse, mutect2, varscan2
- CSMD3 | c.9613A>G p.M3205V (on ENST00000297405 / NM_001363185.1; = p.M3036V on NM_052900.3) | Missense Mutation (SNP) | VAF 34/303 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as rs762522299, COSV52331748; called by muse, mutect2, varscan2
- DLGAP3 | c.371A>T p.Q124L | Missense Mutation (SNP) | VAF 124/412 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV99332805; called by muse, mutect2, varscan2
- DUOX2 | c.2831G>T p.G944V | Missense Mutation (SNP) | VAF 96/354 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.147); catalogued as rs1566973702; called by muse, mutect2, varscan2
- IL1RAPL1 | c.911G>A p.R304K | Missense Mutation (SNP) | VAF 80/302 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.021); catalogued as COSV100150938; called by mutect2, varscan2
- INO80 | c.1991G>A p.R664H | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62737472, COSV62739062; called by muse, mutect2
- IRX3 | c.65C>A p.A22D | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as rs1372716324, COSV61668654; called by muse, mutect2, varscan2
- ITPRID1 | c.151A>G p.I51V | Missense Mutation (SNP) | VAF 30/106 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs1240277622; called by mutect2, varscan2
- KIF18B | c.2252G>T p.R751M (on ENST00000593135 / NM_001265577.2; = p.R763M on NM_001264573.2) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV59271185; called by muse, varscan2
- LAMA1 | c.6515G>A p.R2172Q | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs746251281; called by muse, mutect2, varscan2
- MTTP | c.618G>A p.Q206= | Splice Region (SNP) | VAF 83/255 reads (33%) | catalogued as rs1454222756; called by muse, mutect2, varscan2
- MTUS2 | c.434A>G p.D145G | Missense Mutation (SNP) | VAF 8/232 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1048900685; called by muse, mutect2
- NAT10 | c.2668C>T p.Q890* | Nonsense Mutation (SNP) | VAF 49/263 reads (19%) | catalogued as rs1246893673; called by muse, mutect2, varscan2
- NKX2-5 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.2); catalogued as COSV61299276; called by muse, mutect2
- NOTCH2 | c.6973C>T p.Q2325* | Nonsense Mutation (SNP) | VAF 20/73 reads (27%) | catalogued as CM112324, COSV56682148; called by muse, mutect2, varscan2
- NPR3 | c.502G>A p.D168N | Missense Mutation (SNP) | VAF 76/213 reads (36%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV54090080; called by muse, mutect2, varscan2
- NR5A2 | c.1330G>C p.D444H (on ENST00000367362 / NM_205860.3; = p.D398H on NM_003822.5) | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52660360; called by muse, mutect2, varscan2
- OR51M1 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 64/159 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.059); catalogued as rs779170296; called by muse, mutect2, varscan2
- PIKFYVE | c.699G>C p.L233F | Missense Mutation (SNP) | VAF 100/376 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs777357869; called by muse, mutect2, varscan2
- PLEKHA5 | c.910A>T p.I304F | Missense Mutation (SNP) | VAF 76/163 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.043); catalogued as rs1565550836; called by muse, mutect2, varscan2
- PRKDC | c.12049G>C p.E4017Q | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as rs375321876; ClinVar: uncertain significance; called by muse, varscan2
- SLC38A4 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 88/163 reads (54%) | SIFT tolerated (0.27); PolyPhen probably damaging (1); catalogued as rs1311032019, COSV56969984; called by muse, mutect2, varscan2
- SLC41A3 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 54/179 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1289535326; called by muse, mutect2, varscan2
- SPACA7 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs779002404, COSV52098902; called by muse, mutect2
- TGOLN2 | c.287A>G p.N96S | Missense Mutation (SNP) | VAF 185/515 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.225); catalogued as rs1325016975; called by muse, mutect2, varscan2
- TRIM67 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1223330470; called by muse, mutect2, varscan2
- UNC80 | c.8554C>T p.R2852C | Missense Mutation (SNP) | VAF 84/320 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs1369756905, COSV55897971; called by muse, mutect2, varscan2
- ABCA5 | c.4203_4221del p.K1402Tfs*2 | Frame Shift Del (DEL) | VAF 36/104 reads (35%) | called by mutect2, pindel, varscan2
- ACACA | c.1509G>T p.M503I | Missense Mutation (SNP) | VAF 68/252 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ADAM30 | c.2241A>T p.K747N | Missense Mutation (SNP) | VAF 93/364 reads (26%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADM5 | c.208C>G p.R70G | Missense Mutation (SNP) | VAF 77/273 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- ALDH1L1 | c.2654-7C>G | Splice Region (SNP) | VAF 24/262 reads (9%) | called by muse, mutect2
- AMER1 | c.2426_2436del p.F809* | Frame Shift Del (DEL) | VAF 64/293 reads (22%) | called by mutect2, pindel, varscan2
- ANO1 | c.2296_2324del p.K766Gfs*35 | Frame Shift Del (DEL) | VAF 32/223 reads (14%) | called by mutect2, pindel
- APOB | c.9406C>G p.R3136G | Missense Mutation (SNP) | VAF 117/374 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATP4A | c.665G>A p.C222Y | Missense Mutation (SNP) | VAF 86/309 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- BRCA1 | c.752A>T p.K251M | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- C11orf16 | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 63/260 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- C11orf16 | c.814G>A p.A272T | Missense Mutation (SNP) | VAF 63/262 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- C16orf89 | c.1170A>C p.R390S | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAPN12 | c.804+1G>T p.X268_splice | Splice Site (SNP) | VAF 10/269 reads (4%) | called by muse, mutect2
- CHAMP1 | c.1135T>G p.S379A | Missense Mutation (SNP) | VAF 117/227 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- CHODL | c.677C>A p.P226H | Missense Mutation (SNP) | VAF 61/226 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHRD | c.749G>C p.R250T | Missense Mutation (SNP) | VAF 18/577 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); called by muse, mutect2
- CKAP5 | c.1447G>C p.D483H | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CNGA3 | c.1505T>A p.V502E | Missense Mutation (SNP) | VAF 200/626 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CSPP1 | c.1862G>C p.G621A (on ENST00000676605; = p.G580A on NM_024790.6) | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.799); called by muse, mutect2
- CXCR1 | c.157A>T p.S53C | Missense Mutation (SNP) | VAF 25/356 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2
- DNAJC21 | c.1466G>T p.C489F | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); called by muse, mutect2
- EPB41L3 | c.2790G>C p.Q930H | Missense Mutation (SNP) | VAF 94/151 reads (62%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ERICH3 | c.2590G>A p.A864T | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- EVPL | c.1244C>G p.P415R | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- FER1L5 | c.6271_*15del | Nonstop Mutation (DEL) | VAF 49/199 reads (25%) | called by mutect2, pindel, varscan2
- FGF2 | c.532C>T p.P178S | Missense Mutation (SNP) | VAF 79/156 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- FOXD4L5 | c.839G>A p.G280E | Missense Mutation (SNP) | VAF 146/939 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GABRB1 | c.665A>T p.K222M | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- GABRR2 | c.871C>A p.P291T | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GDPD4 | c.284T>G p.L95R | Missense Mutation (SNP) | VAF 62/240 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- GLCE | c.401_421del p.E134_Y140del | In Frame Del (DEL) | VAF 116/362 reads (32%) | called by mutect2, pindel, varscan2
- GRIK3 | c.1633C>T p.R545* | Nonsense Mutation (SNP) | VAF 52/174 reads (30%) | called by muse, mutect2, varscan2
- IGLV3-27 | c.149dup p.Y50* | Nonsense Mutation (INS) | VAF 79/359 reads (22%) | called by mutect2, pindel, varscan2
- IL34 | c.568_584del p.D190Sfs*57 | Frame Shift Del (DEL) | VAF 32/104 reads (31%) | called by mutect2, pindel, varscan2
- JCAD | c.2878G>A p.E960K | Missense Mutation (SNP) | VAF 123/285 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- L3MBTL1 | c.1519C>T p.P507S (on ENST00000418998 / NM_001377303.1; = p.P417S on NM_015478.7) | Missense Mutation (SNP) | VAF 60/203 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MACF1 | c.14930C>A p.S4977Y (on ENST00000372915; = p.S2910Y on NM_012090.5) | Missense Mutation (SNP) | VAF 85/317 reads (27%) | called by muse, mutect2, varscan2
- MAP3K19 | c.1628A>T p.K543M | Missense Mutation (SNP) | VAF 74/224 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MICA | c.541C>A p.H181N | Missense Mutation (SNP) | VAF 63/264 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- MTUS1 | c.1430_1445del p.P477Qfs*9 | Frame Shift Del (DEL) | VAF 98/237 reads (41%) | called by mutect2, pindel, varscan2
- MYO7A | c.1489G>C p.D497H | Missense Mutation (SNP) | VAF 97/430 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NLGN1 | c.583A>T p.S195C | Missense Mutation (SNP) | VAF 93/515 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NOD1 | c.1012G>T p.V338F | Missense Mutation (SNP) | VAF 12/300 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.013); called by muse, mutect2
- NONO | c.461A>G p.N154S | Missense Mutation (SNP) | VAF 46/490 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- PARD3 | c.3572A>C p.Q1191P | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated, low confidence (0.29); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PBXIP1 | c.395C>A p.S132* | Nonsense Mutation (SNP) | VAF 70/179 reads (39%) | called by muse, mutect2, varscan2
- PCDHA13 | c.1069C>G p.L357V | Missense Mutation (SNP) | VAF 81/266 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PEX1 | c.250C>A p.L84I | Missense Mutation (SNP) | VAF 28/343 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PI4K2B | c.354A>T p.E118D | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PLXNA2 | c.1590G>T p.W530C | Missense Mutation (SNP) | VAF 69/252 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PPP4C | c.5C>G p.A2G | Missense Mutation (SNP) | VAF 7/161 reads (4%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); called by muse, mutect2
- PRPF8 | c.5988T>G p.N1996K | Missense Mutation (SNP) | VAF 60/352 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- RAB33A | c.403T>A p.C135S | Missense Mutation (SNP) | VAF 112/243 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RAD51B | c.1188G>C p.Q396H | Missense Mutation (SNP) | VAF 24/455 reads (5%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); called by muse, mutect2
- RGPD3 | c.3234A>C p.K1078N | Missense Mutation (SNP) | VAF 222/709 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RPAP1 | c.938C>T p.A313V | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2
- SBSN | c.571G>T p.G191* | Nonsense Mutation (SNP) | VAF 162/579 reads (28%) | called by muse, mutect2, varscan2
- SCN2A | c.1310A>G p.E437G | Missense Mutation (SNP) | VAF 54/255 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SHB | c.1293C>A p.S431R | Missense Mutation (SNP) | VAF 56/290 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SHOX2 | c.159C>A p.S53R | Missense Mutation (SNP) | VAF 81/267 reads (30%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- SLC6A19 | c.1474A>T p.I492F | Missense Mutation (SNP) | VAF 246/554 reads (44%) | SIFT tolerated (0.31); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- SLCO2B1 | c.1859_1873del p.S620_T624del | In Frame Del (DEL) | VAF 22/240 reads (9%) | called by mutect2, pindel
- SMIM26 | c.263C>T p.T88I | Missense Mutation (SNP) | VAF 90/338 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SP140 | c.1069T>A p.S357T | Missense Mutation (SNP) | VAF 58/215 reads (27%) | SIFT tolerated (0.73); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- SUPT5H | c.339_341del p.V114del | In Frame Del (DEL) | VAF 20/80 reads (25%) | called by pindel, varscan2
- SYNE2 | c.9887C>G p.P3296R | Missense Mutation (SNP) | VAF 20/289 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.118); called by muse, mutect2
- TAFA4 | c.402_411+4del p.X134_splice | Splice Site (DEL) | VAF 61/133 reads (46%) | called by mutect2, pindel, varscan2
- TCOF1 | c.3820T>G p.S1274A (on ENST00000377797 / NM_001135243.1; = p.S1197A on NM_000356.4) | Missense Mutation (SNP) | VAF 120/369 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- TERF2 | c.1171G>C p.E391Q | Missense Mutation (SNP) | VAF 69/231 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- TFEC | c.238G>C p.A80P | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TNPO3 | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 73/260 reads (28%) | SIFT tolerated (0.95); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- TSHZ1 | c.1841C>T p.S614F (on ENST00000580243 / NM_001308210.2; = p.S569F on NM_005786.6) | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- USP14 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 59/228 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VCPIP1 | c.230A>C p.H77P | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- VNN1 | c.452dup p.C152Vfs*4 | Frame Shift Ins (INS) | VAF 60/159 reads (38%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.9401_9407del p.G3134Vfs*64 | Frame Shift Del (DEL) | VAF 27/69 reads (39%) | called by mutect2, pindel*
- ZNF213 | c.801C>G p.D267E | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.91); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF496 | c.532G>T p.G178W | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF514 | c.436A>G p.T146A | Missense Mutation (SNP) | VAF 105/290 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTSL2 | c.1128A>C p.S376= | Silent (SNP) | VAF 68/220 reads (31%) | called by muse, mutect2, varscan2
- FASTKD1 | c.231G>A p.K77= | Silent (SNP) | VAF 38/182 reads (21%) | catalogued as COSV70006980; called by muse, mutect2, varscan2
- GALNT14 | c.411C>T p.R137= | Silent (SNP) | VAF 39/169 reads (23%) | called by muse, mutect2, varscan2
- GLI1 | c.669A>G p.R223= | Silent (SNP) | VAF 77/173 reads (45%) | called by muse, mutect2, varscan2
- GPR149 | c.2001G>T p.G667= | Silent (SNP) | VAF 30/142 reads (21%) | catalogued as COSV101078152, COSV67668118; called by muse, mutect2, varscan2
- HRH2 | c.339C>T p.S113= | Silent (SNP) | VAF 102/453 reads (23%) | called by muse, mutect2, varscan2
- IGKV2D-24 | c.204T>C p.P68= | Silent (SNP) | VAF 89/312 reads (29%) | catalogued as rs1351973007; called by muse, mutect2, varscan2
- LILRB4 | c.390G>A p.P130= | Silent (SNP) | VAF 83/182 reads (46%) | catalogued as rs372420039; called by muse, mutect2, varscan2
- MB21D2 | c.1212C>A p.R404= | Silent (SNP) | VAF 68/368 reads (18%) | catalogued as COSV101165030; called by muse, mutect2, varscan2
- METTL18 | c.396G>A p.V132= | Silent (SNP) | VAF 57/201 reads (28%) | called by muse, mutect2, varscan2
- MGAT5B | c.1221C>G p.A407= | Silent (SNP) | VAF 44/213 reads (21%) | called by muse, mutect2, varscan2
- MUC22 | c.168T>G p.T56= | Silent (SNP) | VAF 27/177 reads (15%) | called by muse, mutect2, varscan2
- NF1 | c.2838C>T p.D946= | Silent (SNP) | VAF 99/355 reads (28%) | catalogued as rs147188807; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR5M8 | c.759C>A p.T253= | Silent (SNP) | VAF 51/139 reads (37%) | catalogued as rs777315851; called by muse, mutect2, varscan2
- OR6C75 | c.657C>A p.I219= | Silent (SNP) | VAF 124/243 reads (51%) | catalogued as rs375544134; called by muse, mutect2, varscan2
- OR9Q2 | c.222G>A p.S74= | Silent (SNP) | VAF 50/209 reads (24%) | catalogued as rs760143408, COSV61113093; called by muse, mutect2, varscan2
- OXER1 | c.1197G>A p.R399= | Silent (SNP) | VAF 78/255 reads (31%) | catalogued as rs142162926; called by muse, mutect2, varscan2
- PITPNM2 | c.3303G>C p.L1101= | Silent (SNP) | VAF 85/173 reads (49%) | called by muse, mutect2, varscan2
- PRPF6 | c.825G>A p.T275= | Silent (SNP) | VAF 93/287 reads (32%) | catalogued as rs201487454, COSV99411686; called by muse, mutect2, varscan2
- ROR2 | c.2349C>T p.N783= | Silent (SNP) | VAF 64/161 reads (40%) | catalogued as rs761291207, COSV100995391; ClinVar: likely benign; called by muse, mutect2, varscan2
- SCNN1B | c.1902C>T p.D634= | Silent (SNP) | VAF 28/205 reads (14%) | catalogued as rs995687895; called by muse, mutect2, varscan2
- SEPTIN12 | c.912C>T p.N304= | Silent (SNP) | VAF 72/248 reads (29%) | called by muse, mutect2, varscan2
- SHC3 | c.1263A>T p.A421= | Silent (SNP) | VAF 28/102 reads (27%) | called by muse, mutect2
- SLC12A1 | c.2925C>T p.I975= | Silent (SNP) | VAF 43/197 reads (22%) | called by muse, mutect2, varscan2
- SVEP1 | c.2637C>T p.Y879= | Silent (SNP) | VAF 44/126 reads (35%) | called by muse, mutect2, varscan2
- TBC1D9B | c.2550C>T p.S850= | Silent (SNP) | VAF 128/269 reads (48%) | called by muse, mutect2, varscan2
- TMEM186 | c.351G>C p.L117= | Silent (SNP) | VAF 78/279 reads (28%) | called by muse, mutect2, varscan2
- TMX2 | c.741T>G p.S247= | Silent (SNP) | VAF 39/175 reads (22%) | called by muse, mutect2, varscan2
- TPRG1 | c.153T>A p.T51= | Silent (SNP) | VAF 36/899 reads (4%) | called by muse, mutect2
- UBALD1 | c.427C>T p.L143= | Silent (SNP) | VAF 5/14 reads (36%) | called by muse, varscan2
- UBXN7 | c.1455A>C p.V485= | Silent (SNP) | VAF 36/316 reads (11%) | called by muse, varscan2
- WNT10B | c.297C>T p.G99= | Silent (SNP) | VAF 37/68 reads (54%) | called by muse, mutect2, varscan2
- ZNF280A | c.558A>T p.G186= | Silent (SNP) | VAF 26/273 reads (10%) | called by muse, mutect2
- ZNF454 | c.39G>A p.S13= | Silent (SNP) | VAF 72/302 reads (24%) | catalogued as rs770644793, COSV100194756; called by muse, mutect2, varscan2
- ZNF680 | c.570A>T p.S190= | Silent (SNP) | VAF 38/111 reads (34%) | called by muse, mutect2, varscan2
- AC002519.1 | chr16:31793404 T>C | 3'Flank (SNP) | VAF 6/123 reads (5%) | catalogued as rs1392564890; called by muse, mutect2
- AC017104.4 | chr2:231509270 G>T | 5'Flank (SNP) | VAF 97/292 reads (33%) | called by muse, mutect2, varscan2
- AC024940.1 | n.3772T>A | RNA (SNP) | VAF 76/215 reads (35%) | called by muse, mutect2, varscan2
- C19orf12 | c.194-2375C>T | Intron (SNP) | VAF 36/125 reads (29%) | called by muse, mutect2, varscan2
- CAD | c.-40C>G | 5'UTR (SNP) | VAF 66/249 reads (27%) | called by muse, mutect2, varscan2
- CMC2 | c.154-2206del | Intron (DEL) | VAF 20/72 reads (28%) | called by mutect2, pindel, varscan2
- FMNL1 | c.3211+25C>G | Intron (SNP) | VAF 20/234 reads (9%) | called by muse, mutect2
- FRY | c.8470-1760G>T | Intron (SNP) | VAF 30/77 reads (39%) | called by muse, mutect2, varscan2
- GHRHR | c.974+21G>C | Intron (SNP) | VAF 64/294 reads (22%) | called by muse, mutect2, varscan2
- KRT17P5 | n.1178C>G | RNA (SNP) | VAF 45/267 reads (17%) | called by muse, mutect2, varscan2
- MRNIP | chr5:179860595 A>C | 5'Flank (SNP) | VAF 32/416 reads (8%) | called by muse, mutect2
- PKD1P6 | n.4205G>A | RNA (SNP) | VAF 129/500 reads (26%) | catalogued as rs764452747; called by muse, mutect2, varscan2
- PLXNC1 | c.3775+118_3775+131del | Intron (DEL) | VAF 23/96 reads (24%) | called by mutect2, pindel, varscan2
- PRPF39 | c.451-325C>G | Intron (SNP) | VAF 18/167 reads (11%) | called by muse, mutect2, varscan2
- SFTPA1 | c.-23-172C>T | Intron (SNP) | VAF 37/68 reads (54%) | called by muse, mutect2, varscan2
- SIGLEC10 | c.706+45G>C | Intron (SNP) | VAF 28/108 reads (26%) | called by muse, mutect2, varscan2
- TULP3 | c.-47C>T | 5'UTR (SNP) | VAF 10/32 reads (31%) | catalogued as rs199562240; called by muse, varscan2
- ZNF599 | c.241+1727C>A | Intron (SNP) | VAF 56/174 reads (32%) | called by muse, mutect2, varscan2
- ZSWIM7 | c.-33C>T | 5'UTR (SNP) | VAF 134/267 reads (50%) | catalogued as rs771857833; called by muse, mutect2, varscan2
